Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5762, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5762-01A (Primary Tumor).

TCGA-CH-5762

Diagnosis

1. Predominantly poorly differentiated adenocarcinoma of the prostate in the peripheral zone on both sides with perineural infiltration and invasion of the lymph vessels. Maximum tumor diameter 2 cm. Right lateral infiltration of the periprostatic fatty connective tissue. Focal infiltration of the right seminal vesicle. In the apex region on both sides widespread contact with the color-labeled preparation margin (contact area measuring max. 8 mm).
2. Fatty tissue with 4 tumor-free lymph nodes.
3. Fatty tissue with 3 tumor-free lymph nodes.

Summary tumor classification: pT3b, L1, V0, R1; pN0 (0/7); Gleason 4+3 = 7 (Gleason 4: approx. 70%).

Source: NCI Genomic Data Commons file fcf9c292-87d3-4619-a46e-ad76234a52a8 (TCGA-CH-5762.21608393-74F2-4A7B-AAF4-9B02CB7AFC94.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).